CCDI case PBBSFL — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/9031ec47-e462-4f17-8d91-ce63c82c949c

Demographics
Sex at birth: female; Race: black or african american.

Diagnoses (1)
1. Astroblastoma: ICD-O-3 morphology code: 9430/3; Tissue or organ of origin: Parietal lobe; Age at diagnosis: 13.2 years (4,805 days).

Biospecimens (3 samples)
- Sample 0DFPU5: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DFPU6: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DFPU7: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
